Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CZ-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: F

Collected:

Accession:

Received

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE.

LOCATION - LEFT LOBE

MULTIFOCAL - NO

SIZE - 1.0 CM

Extrathyroidal extension - absent

Lymphovascular invasion - absent

Resection margins - negative

Background thyroid: Adenomatous hyperplasia

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF SIX LYMPH NODES, LEFT.

Periglandular extracapsular extension absent

Remnant of thymus gland, no tumor present.

(B) RIGHT FACIAL LYMPH NODE:

One lymph node, no tumor present (0/1).

(C) SUPERHYOID DISSECTION LEVEL I:

Pleomorphic adenoma, (2.0 cm) of submandibular gland, margins free of tumor.

105-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
h
10/15/11

Entire report and diagnosis completed by .

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - An asymmetric thyroid. The left lobe (4.5 x 3.0 x 2.0 cm) is distended by a central well-circumscribed soft pink-tan mass (2.2 x 1.7 x 1.5 cm) located in the central portion of the left lobe. Two additional nodules are present in the lower portion of the lobe, a 0.6 cm well-circumscribed more laterally and a firm nodule (1.0 x 0.8 x 0.8 cm in the inferior aspect of the lobe). This lower most firm nodule shows papillary projections on cut surface and is confined to the thyroid.

The isthmus (1.5 x 0.5 x 0.3 cm) is unremarkable. The right lobe (5.0 x 2.0 x 1.0 cm) is also unremarkable. A well-circumscribed nodule is noted in the right inferior location (0.5 x 0.3 x 0.3 cm).

SECTION CODE: A1, A2, representative sections of the right lobe superior and inferior (A2 with possible parathyroid); A3, A4, isthmus and surrounding soft tissue; A5-A8, large left thyroid nodule; A9, A10, adjacent more lateral nodule; A11, A12, inferior firm (1.0 cm) nodule.

(B) RIGHT FACIAL LYMPH NODE (FROZEN SECTION) - Adipose tissue with lymph node. Dissection reveals a 1.3 x 1.0 x 0.5 cm lymph node candidate, serially sectioned and entirely submitted for frozen section diagnosis in B1-B3. /

*FS/DX: NO TUMOR PRESENT.

(C) SUPERHYOID DISSECTION, LEVEL I - A 3.0 x 2.5 x 2.0 cm submandibular tissue. A 2.0 cm in diameter tan-white well circumscribed and encapsulated firm and exophytic nodule is present attached to the major salivary gland by a fibrous pedicle.

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB.
Physician.

Sex: F

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

A portion of the specimen including nodule is submitted for frozen section in C1; C2-C4, representative section of salivary gland; C5-C8, nodule entirely submitted.

*FS/DX: PLEOMORPHIC ADENOMA WITH EPITHELIAL ONCOCYTIC AND METAPLASTIC CHANGE.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 26fcc2da-b396-4d87-bc79-4143cd4f2ff6 (TCGA-EL-A3CZ.3C4CDCCA-488D-40B2-96AA-1D7B78669FE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).